Somatic mutation profile of tumor specimen TCGA-AA-A01K-01A (aliquot TCGA-AA-A01K-01A-01W-A00E-09) from TCGA case TCGA-AA-A01K, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 74.0 years (27,029 days).
Specimen TCGA-AA-A01K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0df26f6-c95e-467c-9392-964a8320f179.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A01K-10A (Blood Derived Normal), aliquot TCGA-AA-A01K-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53007320-7b80-4054-993c-1614be2708d9

The open-access MAF lists 144 somatic variants for this specimen: 113 protein-altering or splice-affecting, 29 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 29, Nonsense Mutation 7, Splice Site 5, Frame Shift Ins 2, Frame Shift Del 2, RNA 2, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 60/200 reads (30%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.4285C>T p.Q1429* | Nonsense Mutation (SNP) | VAF 81/313 reads (26%) | hotspot (GDC flag); catalogued as rs74535574, HM050024, COSV57322632, COSV57333893; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 76/450 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PDHA1 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 272/431 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs199959402, CM941151, COSV63327751; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 34/142 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTN2 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 117/445 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63974372; called by muse, mutect2, varscan2
- ALDH1B1 | c.242A>G p.K81R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV66619843; called by muse, mutect2
- ANGPT2 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 185/223 reads (83%) | SIFT tolerated (0.05); PolyPhen benign (0.18); catalogued as rs760458544, COSV57337388; called by muse, mutect2, varscan2
- ANKS1B | c.1031C>A p.S344* | Nonsense Mutation (SNP) | VAF 27/152 reads (18%) | catalogued as COSV61353917; called by muse, mutect2, varscan2
- ANLN | c.3196G>C p.E1066Q | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV56076754; called by muse, mutect2, varscan2
- ATAD2B | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as rs1417847113, COSV53199587; called by muse, mutect2, varscan2
- ATP8B1 | c.2809C>G p.L937V | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52176319; called by muse, mutect2, varscan2
- C10orf71 | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.708); catalogued as COSV60508459; called by muse, mutect2, varscan2
- CABP5 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 56/259 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs766598543, COSV53152854; called by muse, mutect2
- CCNB1 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV56510240, COSV99841157; called by muse, mutect2, varscan2
- CEP170 | c.1006T>C p.W336R | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60509694; called by muse, mutect2, varscan2
- CEP83 | c.1244A>T p.H415L | Missense Mutation (SNP) | VAF 163/616 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV60408632; called by muse, mutect2, varscan2
- CFAP47 | c.4739A>T p.K1580M | Missense Mutation (SNP) | VAF 112/486 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV57974210; called by muse, mutect2, varscan2
- CHD7 | c.3566G>A p.R1189H | Missense Mutation (SNP) | VAF 237/369 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1554599432, CM137512, COSV71111282; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLU | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769830551, COSV57066921; called by muse, mutect2, varscan2
- CNGB3 | c.2186A>T p.E729V | Missense Mutation (SNP) | VAF 122/399 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as COSV60690756; called by muse, mutect2, varscan2
- COL4A6 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 97/517 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57868071; called by muse, mutect2, varscan2
- CPEB4 | c.1055G>A p.S352N | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV54169166; called by muse, mutect2
- CTNNB1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 83/242 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1245266458, COSV62695900; called by muse, varscan2
- CUBN | c.2276G>A p.S759N | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV64717192; called by muse, mutect2, varscan2
- CYLC2 | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 51/243 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV66337849; called by muse, mutect2, varscan2
- DBR1 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375979874; called by muse, mutect2, varscan2
- EFCAB5 | c.568T>A p.L190I | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57930922; called by muse, mutect2, varscan2
- FBN2 | c.5019C>A p.F1673L | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52517294; called by muse, mutect2
- FGF6 | c.607C>A p.H203N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57404266; called by muse, mutect2, varscan2
- GLYATL2 | c.590A>T p.Q197L | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54850139; called by muse, mutect2, varscan2
- GPATCH2L | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.095); catalogued as rs1210981161, COSV55048787; called by muse, mutect2, varscan2
- GRIA1 | c.2314C>A p.L772I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as COSV53605692; called by muse, mutect2, varscan2
- GUCY1A2 | c.1277G>A p.C426Y | Missense Mutation (SNP) | VAF 75/344 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.883); catalogued as COSV56488449; called by muse, mutect2, varscan2
- H3C4 | c.244G>C p.D82H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.262); catalogued as COSV61912001; called by muse, mutect2, varscan2
- HK2 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 2/13 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1224700820; called by muse, mutect2
- IL1RAPL2 | c.1940C>T p.T647M | Missense Mutation (SNP) | VAF 89/372 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); catalogued as rs367966545, COSV100780682, COSV61160689; called by muse, mutect2, varscan2
- JMJD1C | c.6470T>C p.I2157T | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.37); catalogued as COSV59515365; called by muse, mutect2, varscan2
- KIAA0319L | c.1425C>T p.F475= | Splice Region (SNP) | VAF 40/215 reads (19%) | catalogued as COSV57846239; called by muse, mutect2, varscan2
- LONRF2 | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 66/343 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1002070490, COSV101111061, COSV66540873; called by muse, mutect2, varscan2
- LRRC66 | c.2108G>T p.C703F | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV58634246; called by muse, mutect2, varscan2
- MED12 | c.3308C>G p.S1103C | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61341766; called by muse, mutect2, varscan2
- MED13L | c.3712G>T p.A1238S | Missense Mutation (SNP) | VAF 59/309 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56121144; called by muse, mutect2, varscan2
- MS4A10 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV57632776; called by muse, mutect2, varscan2
- NBR1 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs377650248; called by muse, mutect2, varscan2
- NCAM2 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.242); catalogued as COSV53078803; called by muse, mutect2, varscan2
- NCKAP1L | c.2671A>C p.M891L | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV53207557; called by muse, mutect2, varscan2
- NLGN4X | c.1877G>A p.R626Q | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.279); catalogued as rs1291813149, COSV52020714; called by muse, mutect2, varscan2
- NLRP13 | c.3029T>C p.L1010P | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61622134; called by muse, mutect2, varscan2
- NR1D1 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52843337; called by muse, mutect2, varscan2
- NTNG1 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as rs939752168, COSV53962757; called by muse, varscan2
- OR10K2 | c.739A>T p.I247F | Missense Mutation (SNP) | VAF 54/279 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV59221356; called by muse, mutect2, varscan2
- PCDH10 | c.1180C>G p.Q394E | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.039); catalogued as COSV52095588; called by muse, mutect2, varscan2
- PCDH9 | c.1761G>C p.K587N | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.871); catalogued as COSV60555200; called by muse, mutect2, varscan2
- PCDHGB3 | c.511T>A p.Y171N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.281); catalogued as COSV53960380; called by muse, mutect2, varscan2
- PDPN | c.35G>A p.G12E (on ENST00000621990; = p.G88E on NM_006474.4) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140760055; called by muse, mutect2, varscan2
- POP1 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748288309, COSV62892326; called by muse, mutect2, varscan2
- PRR16 | c.236C>T p.T79M (on ENST00000407149 / NM_001300783.2; = p.T56M on NM_016644.2) | Missense Mutation (SNP) | VAF 99/538 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201082218, COSV65394799; called by muse, mutect2, varscan2
- PTPRZ1 | c.241A>T p.K81* | Nonsense Mutation (SNP) | VAF 17/345 reads (5%) | catalogued as COSV66437769; called by muse, mutect2
- RABL6 | c.190C>A p.Q64K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV61036211; called by muse, varscan2
- RAPGEF5 | c.912C>G p.I304M (on ENST00000401957 / NM_001367602.2; = p.I607M on NM_012294.5) | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV59784126; called by muse, mutect2, varscan2
- ROBO2 | c.1088A>T p.Q363L | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV59907448, COSV59914061; called by muse, mutect2, varscan2
- RPS11 | c.158_161del p.G53Afs*24 | Frame Shift Del (DEL) | VAF 26/36 reads (72%) | catalogued as COSV54526544; called by mutect2, pindel, varscan2
- RYR2 | c.8945T>G p.F2982C | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63688641; called by muse, mutect2, varscan2
- SLC7A14 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs756436577, COSV51578448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMAD2 | c.917C>G p.S306* | Nonsense Mutation (SNP) | VAF 13/151 reads (9%) | catalogued as rs756901143, COSV50992867; called by muse, mutect2
- SYCP2 | c.3411A>G p.I1137M | Missense Mutation (SNP) | VAF 81/236 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV62768807; called by muse, mutect2, varscan2
- SYT6 | c.746G>A p.R249H (on ENST00000610222 / NM_001366225.1; = p.R164H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as rs139165674, COSV101059648; called by muse, mutect2, varscan2
- TAF15 | c.1469G>A p.R490Q (on ENST00000605844 / NM_139215.3; = p.R487Q on NM_003487.4) | Missense Mutation (SNP) | VAF 26/53 reads (49%) | PolyPhen benign (0.003); catalogued as rs1322413661; called by muse, mutect2, varscan2
- TFEC | c.422del p.K141Rfs*42 | Frame Shift Del (DEL) | VAF 52/168 reads (31%) | catalogued as rs771133493, COSV55406589; called by mutect2, pindel, varscan2
- TRIM4 | c.790C>G p.L264V | Missense Mutation (SNP) | VAF 169/710 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV62469388; called by muse, mutect2, varscan2
- TRIM63 | c.343C>A p.Q115K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65328646; called by muse, mutect2, varscan2
- TUBGCP4 | c.707G>T p.R236I | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV53019444; called by muse, mutect2, varscan2
- UNC13A | c.2939G>A p.R980Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV53197468; called by muse, mutect2
- WDR5B | c.673A>C p.I225L | Missense Mutation (SNP) | VAF 63/230 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV51658378; called by muse, mutect2, varscan2
- WFDC8 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 30/339 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); catalogued as COSV51489885; called by muse, mutect2
- ZNF572 | c.176G>C p.R59T | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV60002033, COSV60002242; called by muse, mutect2, varscan2
- ACAN | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ANLN | c.2686A>T p.K896* | Nonsense Mutation (SNP) | VAF 7/117 reads (6%) | called by muse, mutect2
- CAMK1D | c.278A>C p.H93P | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2
- CCDC85A | c.926T>A p.V309E | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CNKSR2 | c.1265C>T p.S422L | Missense Mutation (SNP) | VAF 47/490 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CTNNA3 | c.843+2T>C p.X281_splice | Splice Site (SNP) | VAF 12/391 reads (3%) | called by muse, mutect2
- ECHDC2 | c.514+2T>C p.X172_splice (on ENST00000371522 / NM_001198961.2; = p.X141_splice on NM_018281.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- EPHA6 | c.2137G>T p.V713F (on ENST00000389672 / NM_001080448.3; = p.V105F on NM_173655.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); called by muse, mutect2
- FRYL | c.5136_5138del p.S1712_S1713delinsR | In Frame Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- GABRE | c.784+2T>C p.X262_splice | Splice Site (SNP) | VAF 26/148 reads (18%) | called by muse, mutect2, varscan2
- GTF3C1 | c.847C>A p.L283M | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- H2AC20 | c.*1dup | Frame Shift Ins (INS) | VAF 16/74 reads (22%) | called by mutect2, pindel, varscan2
- ICE2 | c.44A>T p.D15V | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- IL18RAP | c.885C>G p.D295E | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2
- IQCH | c.2120C>T p.S707F | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.343); called by muse, mutect2
- IRF4 | c.401_402insC p.K134Nfs*78 | Frame Shift Ins (INS) | VAF 3/23 reads (13%) | called by mutect2, pindel
- KRT33B | c.859C>A p.Q287K | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- LINS1 | c.632-1G>C p.X211_splice | Splice Site (SNP) | VAF 73/145 reads (50%) | called by muse, mutect2, varscan2
- MYO5A | c.1216C>A p.H406N | Missense Mutation (SNP) | VAF 28/450 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- NBEA | c.4415T>C p.L1472P | Missense Mutation (SNP) | VAF 10/269 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2
- PAPPA | c.2354T>G p.L785R | Missense Mutation (SNP) | VAF 27/566 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCD | c.807C>A p.H269Q | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC17A5 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 323/659 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- SLC30A8 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 175/560 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SPA17 | c.155-1G>C p.X52_splice | Splice Site (SNP) | VAF 32/124 reads (26%) | called by muse, mutect2, varscan2
- SREBF2 | c.2432C>A p.A811D | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM106B | c.98G>A p.S33N | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- TRAV6 | c.69C>G p.F23L | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TTC12 | c.911C>A p.A304E | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TTN | c.46145G>T p.G15382V (on ENST00000591111; = p.G7958V on NM_003319.4) | Missense Mutation (SNP) | VAF 124/634 reads (20%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WASHC2C | c.3715A>G p.I1239V (on ENST00000336378; = p.I1218V on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZCCHC4 | c.1476G>T p.M492I | Missense Mutation (SNP) | VAF 205/806 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF266 | c.1303C>A p.P435T | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF304 | c.620G>T p.S207I | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- A2ML1 | c.1029C>A p.T343= | Silent (SNP) | VAF 67/142 reads (47%) | catalogued as COSV55291590; called by muse, mutect2, varscan2
- ADAMTS20 | c.204C>T p.S68= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs957307979, COSV67131786; called by muse, mutect2, varscan2
- APOBEC3D | c.939C>T p.T313= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV53326871; called by muse, mutect2, varscan2
- C16orf72 | c.477T>C p.A159= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as COSV59916125; called by muse, mutect2, varscan2
- CACNA1E | c.450C>T p.F150= | Silent (SNP) | VAF 80/264 reads (30%) | catalogued as COSV62398566; called by muse, mutect2, varscan2
- EFCAB3 | c.12A>T p.S4= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV59502376; called by muse, mutect2, varscan2
- FAT4 | c.12498C>T p.G4166= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as rs190749052; called by muse, mutect2, varscan2
- FILIP1L | c.1539A>G p.K513= (on ENST00000354552 / NM_182909.3; = p.K273= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 109/404 reads (27%) | catalogued as COSV58769786; called by muse, mutect2, varscan2
- FREM2 | c.8496C>T p.C2832= | Silent (SNP) | VAF 22/590 reads (4%) | called by muse, mutect2
- GCG | c.144C>T p.N48= | Silent (SNP) | VAF 170/490 reads (35%) | catalogued as rs200220805; called by muse, mutect2, varscan2
- GJA8 | c.363C>T p.N121= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV53789349, COSV99569742; called by muse, mutect2, varscan2
- ITGA6 | c.2181C>T p.P727= (on ENST00000442250; = p.P688= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/223 reads (16%) | catalogued as COSV51227267; called by muse, mutect2, varscan2
- LRP1B | c.2622C>T p.S874= | Silent (SNP) | VAF 58/228 reads (25%) | catalogued as rs775728525, COSV63341565; called by muse, mutect2
- MUC16 | c.14967T>C p.F4989= | Silent (SNP) | VAF 90/623 reads (14%) | catalogued as COSV67470298; called by muse, mutect2, varscan2
- NPAS4 | c.1971C>A p.G657= | Silent (SNP) | VAF 197/215 reads (92%) | catalogued as rs552263741, COSV60649634, COSV60650817; called by muse, mutect2, varscan2
- NPHS1 | c.2670G>A p.T890= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs759846180, CD082165, COSV62288210; called by muse, mutect2, varscan2
- NUDT7 | c.438G>T p.L146= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as COSV51745617; called by muse, mutect2, varscan2
- PARP11 | c.489C>T p.R163= | Silent (SNP) | VAF 290/514 reads (56%) | catalogued as COSV57395233; called by muse, mutect2, varscan2
- PCDHB8 | c.9C>T p.A3= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs782707949, COSV50773492, COSV99175502; called by muse, varscan2
- PPP1CC | c.135C>A p.I45= | Silent (SNP) | VAF 37/187 reads (20%) | catalogued as COSV58583642; called by muse, mutect2, varscan2
- SLC25A52 | c.558G>A p.L186= (on ENST00000672005; = p.L176= on NM_001034172.4) | Silent (SNP) | VAF 4/92 reads (4%) | called by muse, mutect2
- SLC5A11 | c.1998C>T p.C666= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs777534080, COSV61741927; called by muse, mutect2, varscan2
- TCP11L1 | c.555C>A p.G185= | Silent (SNP) | VAF 8/99 reads (8%) | called by muse, mutect2
- TOX | c.816T>C p.F272= | Silent (SNP) | VAF 85/408 reads (21%) | catalogued as COSV63846560; called by muse, mutect2, varscan2
- UTP20 | c.3423G>A p.Q1141= | Silent (SNP) | VAF 107/348 reads (31%) | catalogued as COSV55378257; called by muse, mutect2, varscan2
- ZBED2 | c.484A>C p.R162= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- ZFP37 | c.435T>C p.T145= | Silent (SNP) | VAF 111/593 reads (19%) | catalogued as COSV65287213; called by muse, mutect2, varscan2
- ZNF426 | c.1524G>A p.E508= | Silent (SNP) | VAF 40/218 reads (18%) | called by muse, varscan2
- ZNF816 | c.9T>C p.R3= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV54411348; called by muse, mutect2, varscan2
- FOLH1B | n.1093C>G | RNA (SNP) | VAF 95/218 reads (44%) | called by muse, mutect2, varscan2
- SNORD115-7 | n.15C>A | RNA (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
